Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2687, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2687-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Atypical node
- B. Rectosigmoid tissue procurement

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectocancer.

GROSS DESCRIPTION

A. Received fresh labeled "atypical node" is a 0.7 cm. in greatest dimension soft tan pink tissue in keeping with lymph node with a moderate amount of associated glistening golden yellow adipose tissue. The specimen is entirely submitted in one block.

B. Received fresh labeled "rectosigmoid" is a previously unopened 30 cm. segment of distal colon surfaced by smooth glistening tan pink serosa and scabrous adventia with a copious amount of attached mesocolon. The proximal and distal margins measure 5.0 and 9.03 cm. in circumference respectively. On opening, there is a circumferential, 8.0 x 5.2 cm. centrally necrotic tan pink-red tumor mass with raised rolled edges 4 cm. from the distal margin. On sectioning, the tumor has a maximal thickness of 1.6 cm. grossly extending through the muscularis. The tumor extends to within 0.5 cm. of the inked free serosal surface and to within 3 cm. of the inked adventitial surface (see blocks 3, and 4 and 5 respectively). A portion of tumor and a portion of normal tissue are submitted for procurement as requested. The remaining mucosa is unremarkable tan pink with regular folds and the wall averages 0.6 cm. in thickness. A few uncomplicated diverticula are present. Multiple soft tan pink to rubbery tan white tissues in keeping with lymph nodes measuring up to 1.6 cm. in greatest dimension are recovered from the attached mesocolon. Representative sections are submitted in 15 blocks as labeled.

GROSS DESCRIPTION

BLOCK SUMMARY: 1 - proximal margin; 2 - tumor to distal margin (post fixation); 3 - tumor full thickness to inked free radial serosal surface (black); 4 and 5 - tumor full thickness to inked adventitial surface (black; point of continuity between sections inked green); 6 - central tumor; 7 - tumor to proximal mucosa; 8 and 9 - random normal mucosa; 10 and 11 - six whole lymph nodes per cassette; 12 through 14 - one bisected lymph node per cassette; 15 - one trisected lymph node.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

A. Microscopic examination reveals a benign reactive lymph node. No metastatic tumor is identified.

B. Microscopic examination of the rectosigmoid resection reveals:

Histologic type: Adenocarcinoma, not otherwise specified.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Tumor invades through the muscularis propria extending

3 mm beyond the muscularis propria into the fat (pT3b).

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative for tumor.

Distance of tumor from closest margin: 3 cm from the circumferential (adventitial/radial) margin.

Vascular invasion: Not identified.

Regional lymph nodes (pN): Metastatic adenocarcinoma in 6 of 16 lymph nodes, the largest metastatic focus is 1.6 cm in greatest dimension (pN2)

Non-lymph node pericolic tumor: Very focally identified.

Distant metastasis (pM): Cannot evaluate (pMX).

Other findings: Some minimal changes of diverticula are noted with

MICROSCOPIC DESCRIPTION

no significant inflammation. The tumor shows marked surface ulceration and stromal sclerosis with a mild number of tumor infiltrating lymphocytes.

5x1, 3x1

DIAGNOSIS

A. Lymph node "atypical" biopsy:

Single lymph node negative for metastatic tumor (0/1).

B. Rectosigmoid, resection:

Moderately differentiated adenocarcinoma, invasive through muscularis propria into pericolic fat (pT3).

Metastatic adenocarcinoma in 6 of 16 lymph nodes (pN2).

The resection margins are negative for tumor.

See microscopic description for template details.

Source: NCI Genomic Data Commons file 1af34575-eb24-41ed-9875-cbf2ae12faf1 (TCGA-AF-2687.A43F102C-EC6C-400F-9D1B-FE5882962937.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).